Somatic mutation profile of tumor specimen TCGA-ZB-A96D-01A (aliquot TCGA-ZB-A96D-01A-11D-A428-09) from TCGA case TCGA-ZB-A96D, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 52.8 years (19,274 days).
Specimen TCGA-ZB-A96D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b5d21d3-3a41-45ab-a44f-c6df8fdae5e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96D-10A (Blood Derived Normal), aliquot TCGA-ZB-A96D-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57ebdeda-8e46-43ff-84a3-0b1caadc6a82

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 42/494 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- EPHB1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67665628, COSV67672070; called by muse, mutect2
- KCNT2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | catalogued as COSV99651569; called by muse, mutect2
- ZC3H4 | c.3656A>G p.N1219S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs1299361689; called by muse, mutect2, varscan2
- GPRC5C | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.03); called by mutect2, varscan2
- HNRNPR | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.122); called by muse, mutect2
- RBMS3 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- TRPV4 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); called by muse, mutect2
- VPS13C | c.10292G>C p.R3431T (on ENST00000644861 / NM_020821.3; = p.R3388T on NM_017684.5) | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ZNF622 | c.372C>A p.D124E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2
- FBXL18 | c.321G>A p.L107= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
